Somatic mutation profile of tumor specimen MMRF_2489_1_BM_CD138pos (aliquot MMRF_2489_1_BM_CD138pos_T1_KHS5U_L11603) from MMRF case MMRF_2489, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.3 years (20,575 days).
Specimen MMRF_2489_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 049a9c3f-14fa-45a7-8248-32f30e578def.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2489_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2489_1_PB_Whole_C3_KHS5U_L11604; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08482f37-c9f4-41d6-aca1-f6d53780963b

The open-access MAF lists 78 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 23, Silent 12, Intron 9, Frame Shift Del 3, 3'Flank 2, 5'UTR 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALAD | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs121912983, CM900009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LZTR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs869320686, CM154934, COSV53144758; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- C1QL1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as rs567512888, COSV53647255; called by muse, mutect2
- CTNND2 | c.1450G>C p.A484P | Missense Mutation (SNP) | VAF 112/385 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100481273, COSV58892684; called by muse, mutect2, varscan2
- IGHV2-70 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs548389762; called by muse, mutect2, varscan2
- IGLV3-1 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 110/203 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs184648956; called by muse, mutect2, varscan2
- PCM1 | c.2879C>T p.S960L | Missense Mutation (SNP) | VAF 112/242 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.395); catalogued as rs1236259577; called by muse, mutect2, varscan2
- PRKDC | c.9714G>A p.M3238I | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV58062490; called by muse, mutect2, varscan2
- ADCY9 | c.1675G>C p.V559L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- AHNAK2 | c.3905G>A p.G1302E | Missense Mutation (SNP) | VAF 69/75 reads (92%) | SIFT tolerated (0.85); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDC42BPB | c.3200G>A p.C1067Y | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYLD | c.347_348del p.R116Kfs*5 | Frame Shift Del (DEL) | VAF 96/140 reads (69%) | called by mutect2, pindel, varscan2
- DLX6 | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMD | c.8440C>G p.L2814V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUOXA2 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 16/462 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR162 | c.1143C>A p.D381E (on ENST00000311268 / NM_019858.2; = p.D97E on NM_014449.2) | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- H4C3 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- HNRNPH2 | c.901A>C p.T301P | Missense Mutation (SNP) | VAF 96/102 reads (94%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KIF1A | c.2939A>C p.K980T | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.697); called by muse, mutect2
- LMNB1 | c.566_570del p.L189* | Frame Shift Del (DEL) | VAF 82/281 reads (29%) | called by mutect2, pindel, varscan2
- MAP3K14 | c.2693C>T p.A898V | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- METTL5 | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 124/247 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PCDHA11 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RASA2 | c.1534_1535del p.F512Lfs*24 | Frame Shift Del (DEL) | VAF 34/210 reads (16%) | called by pindel, varscan2
- SI | c.3679C>A p.Q1227K | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- STAMBP | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- SULT1E1 | c.551G>T p.S184I | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.359); called by muse, mutect2
- ZBBX | c.1694T>C p.F565S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA13 | c.14478C>T p.R4826= | Silent (SNP) | VAF 42/189 reads (22%) | catalogued as rs375778185; called by muse, mutect2, varscan2
- ADAMTS15 | c.2022G>A p.V674= | Silent (SNP) | VAF 83/291 reads (29%) | called by muse, mutect2, varscan2
- ALPK1 | c.366C>T p.D122= | Silent (SNP) | VAF 110/244 reads (45%) | called by muse, mutect2, varscan2
- ATP11A | c.2268C>T p.Y756= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as rs772985347, COSV52105984; called by muse, mutect2, varscan2
- CENPF | c.8883C>A p.V2961= | Silent (SNP) | VAF 35/298 reads (12%) | catalogued as rs956722004; called by muse, mutect2, varscan2
- H4C9 | c.192G>A p.E64= | Silent (SNP) | VAF 57/117 reads (49%) | catalogued as rs150377743, COSV62889809; called by muse, mutect2, varscan2
- HES6 | c.135G>A p.L45= | Silent (SNP) | VAF 26/40 reads (65%) | called by muse, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 70/146 reads (48%) | catalogued as rs367953381; called by muse, varscan2
- JCAD | c.2985A>G p.E995= | Silent (SNP) | VAF 90/162 reads (56%) | called by muse, mutect2
- PDZD2 | c.2835C>A p.L945= | Silent (SNP) | VAF 134/459 reads (29%) | catalogued as COSV56870215; called by muse, mutect2, varscan2
- PLA2G4E | c.1977G>A p.L659= | Silent (SNP) | VAF 75/271 reads (28%) | catalogued as rs567148385; called by muse, mutect2, varscan2
- TRPV1 | c.1806G>A p.G602= | Silent (SNP) | VAF 49/97 reads (51%) | called by muse, mutect2, varscan2
- AFF1 | c.*2345G>T | 3'UTR (SNP) | VAF 26/66 reads (39%) | catalogued as rs143536128; called by muse, mutect2, varscan2
- APOOL | c.*223A>G | 3'UTR (SNP) | VAF 2/13 reads (15%) | called by muse, mutect2
- ARSA | c.-177G>A | 5'UTR (SNP) | VAF 14/225 reads (6%) | called by muse, mutect2
- ATP10B | c.*52C>A | 3'UTR (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- BMP6 | c.*1221_*1251delinsAAT | 3'UTR (DEL) | VAF 34/96 reads (35%) | called by pindel, varscan2*
- C1orf87 | c.*198A>C | 3'UTR (SNP) | VAF 35/60 reads (58%) | called by muse, mutect2, varscan2
- CCDC66 | c.102+1606T>C | Intron (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- CCDC66 | c.102+1607T>A | Intron (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- CDH19 | c.*2636T>G | 3'UTR (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- COMMD9 | chr11:36270077 T>C | 3'Flank (SNP) | VAF 42/132 reads (32%) | called by muse, mutect2, varscan2
- DYNLRB2 | c.80-29dup | Intron (INS) | VAF 45/65 reads (69%) | catalogued as rs1444486436; called by mutect2, pindel, varscan2
- FAT3 | c.*896G>A | 3'UTR (SNP) | VAF 40/168 reads (24%) | called by muse, varscan2
- HEMK1 | c.*2372del | 3'UTR (DEL) | VAF 81/217 reads (37%) | called by mutect2, pindel, varscan2
- HES6 | c.250+14G>A | Intron (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- HMCN1 | c.*540T>C | 3'UTR (SNP) | VAF 51/115 reads (44%) | catalogued as COSV54873986; called by muse, mutect2, varscan2
- IGSF10 | c.*2973C>G | 3'UTR (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- IMMP2L | c.305+875T>G | Intron (SNP) | VAF 32/54 reads (59%) | called by mutect2, varscan2
- LHCGR | c.*743G>A | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- LINC00632 | chrX:140709731 T>C | 5'Flank (SNP) | VAF 141/152 reads (93%) | called by muse, mutect2, varscan2
- MPZL1 | c.*2624C>T | 3'UTR (SNP) | VAF 77/176 reads (44%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.617C>T | RNA (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- NAV3 | c.-93G>A | 5'UTR (SNP) | VAF 52/98 reads (53%) | called by muse, mutect2, varscan2
- PEG3 | c.*1562G>C | 3'UTR (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2
- PELI2 | c.*1253G>A | 3'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- PKIA | chr8:78603707 C>A | 3'Flank (SNP) | VAF 53/128 reads (41%) | called by muse, mutect2, varscan2
- PON2 | c.*16T>G | 3'UTR (SNP) | VAF 74/143 reads (52%) | called by muse, mutect2, varscan2
- POSTN | c.*438T>C | 3'UTR (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- PRKCB | c.*58A>G | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- RBM46 | c.1403-1053T>A | Intron (SNP) | VAF 240/530 reads (45%) | called by muse, mutect2, varscan2
- SH3BGRL2 | c.*2767C>T | 3'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- SMOC2 | c.*1379T>C | 3'UTR (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- STX5 | c.679+85G>T | Intron (SNP) | VAF 26/326 reads (8%) | called by muse, mutect2
- TACC3 | c.2018+71C>T | Intron (SNP) | VAF 54/108 reads (50%) | called by muse, mutect2, varscan2
- TSPAN8 | c.*102G>C | 3'UTR (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- TUBA3C | c.*43C>T | 3'UTR (SNP) | VAF 91/193 reads (47%) | catalogued as rs756389311, COSV101313886; called by muse, mutect2, varscan2
- WNT9A | c.*1077T>C | 3'UTR (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- ZNF211 | c.91-496T>G | Intron (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2
- ZNF664 | c.*9G>T | 3'UTR (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
